Somatic mutation profile of tumor specimen TARGET-30-PASWYR-01A (aliquot TARGET-30-PASWYR-01A-01D) from TARGET case TARGET-30-PASWYR, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.6 years (958 days).
Specimen TARGET-30-PASWYR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 409c3468-b45d-4416-8746-40d61267713c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASWYR-10A (Blood Derived Normal), aliquot TARGET-30-PASWYR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc04e201-8301-4eec-ba37-0d7b850ed011

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as COSV52342821; called by muse, mutect2, varscan2
- CACNG6 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1437887891, COSV53166317; called by muse, mutect2
- CCDC171 | c.1141G>C p.V381L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as COSV52638971; called by muse, mutect2
- CDH23 | c.5611G>T p.A1871S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs766404226, COSV56459625, COSV56484173; called by muse, mutect2
- CLEC4C | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV63582478; called by muse, mutect2, varscan2
- EPHA8 | c.1862G>T p.R621L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV51263394, COSV51265872; called by muse, mutect2, varscan2
- MORC2 | c.1667C>T p.T556M (on ENST00000397641 / NM_001303256.3; = p.T494M on NM_014941.3) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs776665575, COSV53197804; called by muse, mutect2, varscan2
- NLRP11 | c.2607C>A p.S869R | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.885); catalogued as COSV64086616; called by muse, mutect2, varscan2
- PAX5 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs376952815, COSV63914994; called by muse, mutect2, varscan2
- PCDHB10 | c.2062C>A p.L688I | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53377474; called by muse, mutect2, varscan2
- SALL3 | c.1107C>A p.S369R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV73305869, COSV73305936; called by muse, mutect2
- ZNF141 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as rs782456680, COSV53657647, COSV53660870; called by muse, mutect2, varscan2
- ZNF700 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.221); catalogued as rs765415938, COSV54311348, COSV54311818; called by muse, mutect2, varscan2
- ITGA11 | c.2657G>A p.R886K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2
- MUC5AC | c.14428G>T p.A4810S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TSPOAP1 | c.5002G>T p.A1668S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2
- DOCK5 | c.5082G>T p.P1694= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV52399086; called by muse, mutect2, varscan2
- OPTC | c.375G>T p.L125= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs140765067; called by muse, mutect2
- TPM2 | chr9:35682101 G>T | 3'Flank (SNP) | VAF 14/52 reads (27%) | catalogued as COSV61405658; called by muse, mutect2, varscan2
